Gene-level copy-number profile of tumor specimen TCGA-CI-6619-01B from TCGA case TCGA-CI-6619, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 41.9 years (15,322 days).
Specimen TCGA-CI-6619-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-READ.29d9f2c8-d136-4457-b21a-cdb41415f3c6.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CI-6619-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/63df0820-476b-46be-a7bc-5dd9498318e9

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 8; copy number 2: 32; copy number 3: 19,544; copy number 4: 20,592; copy number 5: 9,629; copy number 6: 5,177; copy number 7: 1,500; copy number 8: 1,901; copy number 9: 1,436.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CI-6619-01B-11D-1825-01): tumor purity 0.31, ploidy 4.33, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,436 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:41,261,962–141,308,305, 1,430 genes, copy number 9 (broad region; genes not listed).
- chr22:27,978,014–28,679,865, 6 genes, copy number 9 (within-gene range 3–9): TTC28, AL033538.1, AL033538.2, RN7SL757P, SNORD42, Y_RNA.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
